Somatic mutation profile of tumor specimen TCGA-OR-A5L8-01A (aliquot TCGA-OR-A5L8-01A-11D-A29I-10) from TCGA case TCGA-OR-A5L8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 36.9 years (13,472 days).
Specimen TCGA-OR-A5L8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 655056e3-d2fc-46b6-9b1f-edb3c448bf00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L8-10A (Blood Derived Normal), aliquot TCGA-OR-A5L8-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c197da4f-519e-4e67-8703-171a807385d3

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 55/144 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV60486643; called by muse, mutect2, varscan2
- AKR1B15 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750221215; called by muse, mutect2, varscan2
- ARRDC3 | c.562T>G p.S188A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.867); catalogued as COSV54365675; called by muse, mutect2, varscan2
- ATP1B4 | c.347A>G p.Y116C (on ENST00000218008 / NM_001142447.3; = p.Y112C on NM_012069.5) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486092; called by muse, mutect2, varscan2
- GOT2 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs893034455; called by muse, mutect2, varscan2
- PCDHGA2 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.151); catalogued as rs766521551; called by muse, mutect2, varscan2
- PTN | c.288C>T p.G96= | Splice Region (SNP) | VAF 29/78 reads (37%) | catalogued as rs779082764, COSV61965206; called by muse, mutect2, varscan2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- SLC1A5 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776991536, COSV69467138; called by muse, mutect2, varscan2
- KIR3DL2 | c.761A>T p.H254L | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K14 | c.1924G>A p.V642M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SLC8A2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TASOR | c.2791G>A p.D931N (on ENST00000355628 / NM_001365636.2; = p.D555N on NM_015224.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- THRA | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM245 | c.1921C>A p.L641I | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYO9B | c.2524C>T p.L842= | Silent (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- NRROS | c.1137C>T p.T379= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1057456191, COSV100145305; called by muse, mutect2, varscan2
- ZFHX3 | c.528C>T p.G176= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs760303298; called by muse, mutect2, varscan2
